Surgical pathology report (de-identified scan), TCGA case TCGA-XX-A899, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Spectrum Health, specimen TCGA-XX-A899-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Carcinoma, infiltrating lobular
NOS 8520/3
Site (B) Breast NOS C50.9
(B) Breast, overlapping lesion C50.8
11/22/13

Research Gross Description

year old female multifocal breast cancer

Research Dx

Procedure: Total mastectomy (including nipple and skin)

Lymph node sampling: Sentinel lymph node and axillary dissection

Specimen laterality: Right

Tumor site: Multifocal, lower outer quadrant (majority of tumors) and lower inner quadrant

Tumor size: 2 x 1.5 x 1.3 cm (largest tumor)

Histopathologic type: Lobular with foci of signet ring morphology 0% on top slide.

Histopathologic grade (Nottingham): 2

Mitotic count: 2 mitoses/10 hpf (low proliferative rate)

Tumor focality: Multiple foci of invasive carcinoma

Pathologic tumor stage: pT1c: Tumor greater than 1 cm but less than or equal to 2 cm in greatest dimension

Margin status: See below

Distance of carcinoma from margins:

Anterior: 0.35 mm (microscopic focus)

Posterior: 8 mm

All other margins greater than 1 cm

Associated in situ carcinoma: Yes

Type: LCIS

Extensive (>25% of total tumor): No

Separate (extra-tumoral) foci away from main lesion: Yes

Peritumoral angiolymphatic invasion: Not identified

Dermal angiolymphatic invasion: Not identified

Hormone receptors by properly controlled immunohistochemistry performed on previous core biopsy

Estrogen receptor: Positive

Progesterone receptor: Positive

HER-2/neu (ERBB2): Negative

Pathologic lymph node stage: pN2a: Metastasis in 4-9 axillary lymph nodes (at least one tumor deposit greater than 2.0 mm)

Number of nodes positive for metastasis/total number nodes sampled: 5/22

Maximum diameter of largest lymph node metastasis: 1 cm

Extranodal extension by tumor: Present, focal

Distant metastasis: pM: Not applicable

Additional pathologic findings: Fibrocystic changes

AJCC Staging (7th Edition): pT1c(m) pN2a pM: Not applicable

Research QC

Tumor:

80% tumor nuclei

0% necrosis

20% normal

Normal:

100% breast

[page 2 of 3]
Specimen Process Time

Blood draw time:

Plasma frozen time:

Serum frozen time:

Buffy coat frozen time:

Cold ischemia start time:

Formalin fixation start time:

Total cold ischemia time:

Formalin fixation stopped time:

Total formalin fixation time:

Specimen Weight

Normal

1-512 mg, 2-351 mg, 3-283 mg, 4-372 mg

Tumor

1-262 mg, 2-205 mg, 3-208 mg, 4-317 mg

Specimen Size

Plasma x 3

Serum x 2

Buffy coat x 1

Cryovials x 8

Normal x 4

Tumor x 4: 1-2 lesion site A., 3-4 lesion site B.

FFPE x 8

Normal x 4

Tumor x 4: 1-2 lesion site A., 3-4 lesion site B.

Study

Patient Consent

Yes

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form 4.05 ☒

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Breast Invasive Carcinoma -	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	F

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

Infiltrating lobular carcinoma

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

signet ring morphology

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

pathology report reports the presence of signet ring morphology, however, the topslide contains 0% signet ring.

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file 4af0805d-194f-4e86-a0eb-14d41ad49494 (TCGA-XX-A899.EA8A0A91-7A83-4EC9-B7A0-0C3300D1FD14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).